Somatic mutation profile of tumor specimen C3N-00662-03 (aliquot CPT0087680009) from CPTAC case C3N-00662, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 77.8 years (28,406 days).
Specimen C3N-00662-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 44b36313-da31-411e-b39b-aa5cf081082b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00662-31 (Blood Derived Normal), aliquot CPT0087720002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d22cf5c0-15ec-4c9c-8206-dcec37939af8

The open-access MAF lists 89 somatic variants for this specimen: 55 protein-altering or splice-affecting, 27 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 46, Silent 27, Intron 4, Frame Shift Del 3, Nonsense Mutation 3, Splice Region 2, RNA 1, 3'Flank 1, 5'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.479G>A p.R160K | Missense Mutation (SNP) | VAF 70/229 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.267); catalogued as rs199474752, CM116615, CM1512922, CS072267, CS153433, COSV62207030; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADCY2 | c.3124G>A p.V1042I | Missense Mutation (SNP) | VAF 55/133 reads (41%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.931); catalogued as rs1445100634, COSV57867395; called by muse, mutect2, varscan2
- AICDA | c.331G>A p.A111T | Missense Mutation (SNP) | VAF 189/521 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.604); catalogued as COSV57563759; called by muse, mutect2, varscan2
- ALDOB | c.191T>G p.F64C | Missense Mutation (SNP) | VAF 25/398 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.763); catalogued as rs151219186; called by muse, mutect2
- ANKS4B | c.1030G>A p.D344N | Missense Mutation (SNP) | VAF 65/130 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as rs764130947, COSV61139184; called by muse, mutect2, varscan2
- AQP12A | c.67C>T p.R23W | Missense Mutation (SNP) | VAF 154/435 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0.015); catalogued as rs375647576; called by muse, mutect2, varscan2
- C5orf47 | c.17G>A p.R6Q | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs1209560038, COSV60865383; called by muse, mutect2
- CACNA1E | c.313G>A p.V105I | Missense Mutation (SNP) | VAF 82/251 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV62402667; called by muse, mutect2, varscan2
- CATSPERE | c.545G>A p.R182H | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs754582110; called by muse, mutect2, varscan2
- CCDC22 | c.1346G>A p.R449Q | Missense Mutation (SNP) | VAF 43/288 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.06); catalogued as rs1557114789, COSV100873196; called by muse, mutect2, varscan2
- CS | c.479C>A p.T160N | Missense Mutation (SNP) | VAF 50/130 reads (38%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs768131425; called by muse, mutect2, varscan2
- CTTNBP2 | c.188G>A p.R63Q | Missense Mutation (SNP) | VAF 65/227 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.034); catalogued as rs376703729, COSV99355098, COSV99355281; called by muse, mutect2, varscan2
- CYP2C9 | c.902C>T p.T301M | Missense Mutation (SNP) | VAF 111/153 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs757970831, COSV99582962; called by muse, mutect2, varscan2
- FAM83B | c.1117C>A p.R373S | Missense Mutation (SNP) | VAF 61/154 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.255); catalogued as rs370292018; called by muse, mutect2, varscan2
- GAL3ST1 | c.644G>A p.R215Q | Missense Mutation (SNP) | VAF 203/510 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.035); catalogued as rs1354255119, COSV58891846, COSV58892092; called by muse, mutect2, varscan2
- GRIK5 | c.1126C>T p.R376C | Missense Mutation (SNP) | VAF 70/207 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs370524112; called by muse, mutect2, varscan2
- GRSF1 | c.862C>T p.R288* | Nonsense Mutation (SNP) | VAF 91/252 reads (36%) | catalogued as rs202090491, COSV99635908; called by muse, mutect2, varscan2
- HHIPL2 | c.851G>A p.R284H | Missense Mutation (SNP) | VAF 80/196 reads (41%) | SIFT tolerated (0.3); PolyPhen benign (0.056); catalogued as rs753929029, COSV58564406; called by muse, mutect2, varscan2
- KLRK1 | c.97C>T p.R33* | Nonsense Mutation (SNP) | VAF 41/240 reads (17%) | catalogued as rs1316959170, COSV53700151; called by muse, mutect2, varscan2
- KRT25 | c.265C>T p.R89C | Missense Mutation (SNP) | VAF 116/320 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772479525; called by muse, mutect2, varscan2
- MAGIX | c.50-7C>T | Splice Region (SNP) | VAF 61/135 reads (45%) | catalogued as rs782467623; called by muse, mutect2, varscan2
- MNDA | c.757G>A p.D253N | Missense Mutation (SNP) | VAF 66/149 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs774562125, COSV63740125; called by muse, mutect2, varscan2
- NF1 | c.499_502del p.C167Qfs*10 | Frame Shift Del (DEL) | VAF 95/226 reads (42%) | catalogued as rs786201874; called by pindel, varscan2
- OR8G5 | c.364G>A p.G122S | Missense Mutation (SNP) | VAF 170/242 reads (70%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs1380668530, COSV100422162; called by muse, mutect2, varscan2
- PIK3R6 | c.192G>A p.A64= | Splice Region (SNP) | VAF 66/193 reads (34%) | catalogued as rs149242502, COSV61006412; called by muse, mutect2, varscan2
- PKD1L1 | c.1184A>G p.D395G | Missense Mutation (SNP) | VAF 111/441 reads (25%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0); catalogued as rs757734406, COSV56968327; called by muse, mutect2, varscan2
- PROS1 | c.947G>A p.R316H | Missense Mutation (SNP) | VAF 98/304 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs747259055, CM142190, COSV67776384; called by muse, mutect2, varscan2
- RAB29 | c.224G>A p.R75Q | Missense Mutation (SNP) | VAF 191/398 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs757517652; called by muse, mutect2, varscan2
- RP1 | c.130G>A p.G44R | Missense Mutation (SNP) | VAF 76/276 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs934067828, COSV55127174; called by muse, mutect2, varscan2
- SLC7A2 | c.646G>T p.A216S (on ENST00000494857 / NM_001370338.1; = p.A256S on NM_003046.6) | Missense Mutation (SNP) | VAF 90/218 reads (41%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as COSV50279835; called by muse, mutect2, varscan2
- SMG1 | c.1243C>T p.R415C | Missense Mutation (SNP) | VAF 19/173 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs372333121; called by muse, mutect2
- SMG9 | c.896dup p.Y299* | Nonsense Mutation (INS) | VAF 90/283 reads (32%) | catalogued as rs1393591926; called by mutect2, pindel, varscan2
- STK11 | c.1180G>A p.G394S | Missense Mutation (SNP) | VAF 121/264 reads (46%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.022); catalogued as rs768780695; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TPD52L3 | c.166C>T p.R56C | Missense Mutation (SNP) | VAF 179/433 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.117); catalogued as rs757070996, COSV58828402; called by muse, mutect2, varscan2
- TRPA1 | c.96C>A p.F32L | Missense Mutation (SNP) | VAF 139/347 reads (40%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV51560463; called by muse, mutect2, varscan2
- TRPV5 | c.1817G>A p.R606Q | Missense Mutation (SNP) | VAF 38/323 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs143560130; called by muse, mutect2, varscan2
- ZFHX4 | c.10647del p.L3550Cfs*32 | Frame Shift Del (DEL) | VAF 89/230 reads (39%) | catalogued as COSV50658533; called by mutect2, pindel, varscan2
- ARHGAP45 | c.1312G>A p.G438S | Missense Mutation (SNP) | VAF 30/147 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- CHRFAM7A | c.173G>A p.S58N | Missense Mutation (SNP) | VAF 38/105 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.777); called by mutect2, varscan2
- CYP4B1 | c.496G>A p.D166N | Missense Mutation (SNP) | VAF 57/158 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.35); called by muse, mutect2, varscan2
- DCAF12L2 | c.1019A>T p.N340I | Missense Mutation (SNP) | VAF 86/215 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- EPHA6 | c.833T>A p.F278Y | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- ERICH3 | c.1490A>G p.E497G | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); called by muse, varscan2
- FAM133A | c.484_486del p.K162del | In Frame Del (DEL) | VAF 53/258 reads (21%) | called by pindel, varscan2
- FAM151B | c.677G>A p.S226N | Missense Mutation (SNP) | VAF 118/331 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.38); called by muse, mutect2, varscan2
- MAPK11 | c.152C>T p.A51V | Missense Mutation (SNP) | VAF 82/199 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MLXIP | c.992C>T p.P331L | Missense Mutation (SNP) | VAF 55/159 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- MYO10 | c.2473G>A p.E825K | Missense Mutation (SNP) | VAF 64/274 reads (23%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR5H15 | c.343_344del p.L115Gfs*6 | Frame Shift Del (DEL) | VAF 153/426 reads (36%) | called by mutect2, pindel, varscan2
- POGK | c.280G>T p.D94Y | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.667); called by muse, mutect2, varscan2
- POLR3B | c.839A>G p.Q280R | Missense Mutation (SNP) | VAF 113/368 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- POLR3B | c.840G>T p.Q280H | Missense Mutation (SNP) | VAF 112/368 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- RPAP1 | c.493A>C p.K165Q | Missense Mutation (SNP) | VAF 77/174 reads (44%) | SIFT tolerated (0.48); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- SLC30A10 | c.799C>A p.L267M | Missense Mutation (SNP) | VAF 27/140 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF785 | c.176G>A p.R59Q | Missense Mutation (SNP) | VAF 67/155 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- AHNAK2 | c.10938G>A p.P3646= | Silent (SNP) | VAF 22/414 reads (5%) | catalogued as rs146147417; called by muse, mutect2
- ANK1 | c.4977G>A p.A1659= | Silent (SNP) | VAF 115/313 reads (37%) | catalogued as rs772253626; called by muse, mutect2, varscan2
- ARSH | c.1209C>T p.D403= | Silent (SNP) | VAF 46/119 reads (39%) | catalogued as rs149218715; called by muse, mutect2, varscan2
- CFD | c.453C>T p.A151= | Silent (SNP) | VAF 130/374 reads (35%) | catalogued as rs1240049901; called by muse, mutect2, varscan2
- DHDH | c.843C>T p.N281= | Silent (SNP) | VAF 39/78 reads (50%) | catalogued as rs373504708; called by muse, mutect2, varscan2
- DMXL2 | c.4275T>A p.S1425= | Silent (SNP) | VAF 153/399 reads (38%) | called by muse, mutect2, varscan2
- DNAH11 | c.4890C>T p.F1630= | Silent (SNP) | VAF 48/225 reads (21%) | catalogued as rs569494115, COSV60945336; ClinVar: likely benign; called by muse, mutect2, varscan2
- EBF1 | c.1674C>T p.F558= | Silent (SNP) | VAF 70/183 reads (38%) | catalogued as rs775151734, COSV58188604; called by muse, mutect2, varscan2
- ERG | c.543C>T p.D181= | Silent (SNP) | VAF 177/463 reads (38%) | catalogued as rs372583032; called by muse, mutect2, varscan2
- FAM47A | c.1488C>G p.P496= | Silent (SNP) | VAF 20/51 reads (39%) | called by muse, varscan2
- GIMAP8 | c.1716G>T p.A572= | Silent (SNP) | VAF 102/301 reads (34%) | called by muse, mutect2, varscan2
- GLUL | c.786G>A p.R262= | Silent (SNP) | VAF 78/379 reads (21%) | called by muse, mutect2, varscan2
- IGBP1P2 | c.774C>T p.G258= | Silent (SNP) | VAF 45/141 reads (32%) | catalogued as rs1356820187; called by muse, mutect2, varscan2
- IGHM | c.1038G>A p.S346= | Silent (SNP) | VAF 194/492 reads (39%) | catalogued as rs782283438; called by muse, mutect2, varscan2
- LRRC3B | c.570C>T p.N190= | Silent (SNP) | VAF 78/168 reads (46%) | catalogued as rs375239096; called by muse, mutect2, varscan2
- LTBP4 | c.4452C>T p.G1484= (on ENST00000308370 / NM_001042544.1; = p.G1447= on NM_003573.2) | Silent (SNP) | VAF 20/102 reads (20%) | catalogued as rs904645684, COSV52589203; called by muse, mutect2, varscan2
- MAGEE2 | c.1440C>G p.V480= | Silent (SNP) | VAF 68/204 reads (33%) | catalogued as COSV64897923; called by muse, mutect2, varscan2
- MRTFB | c.627C>T p.A209= | Silent (SNP) | VAF 75/192 reads (39%) | catalogued as rs147706639; called by muse, mutect2, varscan2
- MSLNL | c.1866G>A p.S622= | Silent (SNP) | VAF 63/142 reads (44%) | catalogued as rs533773820; called by muse, mutect2, varscan2
- NEURL1B | c.981G>A p.V327= | Silent (SNP) | VAF 20/55 reads (36%) | catalogued as rs1303670362; called by muse, mutect2, varscan2
- PEX19 | c.192C>T p.F64= | Silent (SNP) | VAF 128/376 reads (34%) | catalogued as rs750771594, COSV63619356; called by muse, mutect2
- PRR23B | c.624A>G p.R208= | Silent (SNP) | VAF 38/142 reads (27%) | called by muse, mutect2, varscan2
- RIMS1 | c.3834C>T p.S1278= | Silent (SNP) | VAF 24/116 reads (21%) | catalogued as rs192801038; called by mutect2, varscan2
- SHANK2 | c.672G>A p.L224= | Silent (SNP) | VAF 65/91 reads (71%) | called by muse, mutect2, varscan2
- TSPYL2 | c.972C>G p.V324= | Silent (SNP) | VAF 72/200 reads (36%) | called by muse, mutect2, varscan2
- ZCWPW1 | c.135T>C p.S45= | Silent (SNP) | VAF 94/375 reads (25%) | called by muse, mutect2, varscan2
- ZNF785 | c.177G>A p.R59= | Silent (SNP) | VAF 65/153 reads (42%) | called by muse, mutect2, varscan2
- AC139769.1 | n.214-4131G>A | Intron (SNP) | VAF 64/504 reads (13%) | catalogued as rs9797512; called by muse, mutect2, varscan2
- AL133467.5 | chr14:95663480 C>T | 3'Flank (SNP) | VAF 78/180 reads (43%) | catalogued as rs747153499; called by muse, mutect2, varscan2
- FUNDC2P2 | n.286C>T | RNA (SNP) | VAF 173/504 reads (34%) | called by muse, mutect2, varscan2
- MGAM | c.4619-13796C>A | Intron (SNP) | VAF 87/192 reads (45%) | catalogued as rs1214188515; called by muse, mutect2, varscan2
- MT4 | c.-29A>T | 5'UTR (SNP) | VAF 86/218 reads (39%) | called by muse, mutect2, varscan2
- SERPINA10 | c.-51+505C>T | Intron (SNP) | VAF 66/159 reads (42%) | catalogued as rs1156643983; called by muse, mutect2, varscan2
- UBL4A | c.155-17C>T | Intron (SNP) | VAF 99/221 reads (45%) | catalogued as rs782756276; called by muse, mutect2, varscan2
